Gene-level copy-number profile of specimen HCM-BROD-0036-C41-85A from HCMI case HCM-BROD-0036-C41, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Ewing sarcoma; Tissue or organ of origin: Bone, NOS; Age at diagnosis: 13.7 years (4,997 days).
Specimen HCM-BROD-0036-C41-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Mixed Adherent Suspension; Preservation method: Frozen; Passage count: 12.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d11bdb02-7a05-469c-b992-ee340cd16a99.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0036-C41-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,712 have no estimate.
https://portal.gdc.cancer.gov/files/84291fe2-a06d-4f37-a413-9c9c6ab541b4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 314; copy number 1: 7,418; copy number 2: 46,213; copy number 3: 4,772; copy number 5: 194.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 194 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:103,364,239–106,235,594, 182 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr14:106,329,432–106,331,563, 2 genes, copy number 5 (within-gene range 1–5): IGHVII-28-1, IGHV3-32.
- chr14:106,342,680–106,344,833, 2 genes, copy number 5 (within-gene range 1–5): IGHVII-30-1, IGHV3-30-2.
- chr14:106,354,448–106,356,591, 2 genes, copy number 5 (within-gene range 1–5): IGHVII-30-21, IGHV3-29.
- chr14:106,418,018–106,418,299, 1 gene, copy number 5 (within-gene range 1–5): IGHVIII-38-1.
- chr14:106,425,359–106,425,654, 1 gene, copy number 5 (within-gene range 1–5): IGHV7-40.
- chr14:106,463,256–106,463,691, 1 gene, copy number 5 (within-gene range 1–5): IGHV3-42.
- chr14:106,472,791–106,481,706, 3 genes, copy number 5 (within-gene range 1–5): IGHVII-43-1, IGHVIII-44, AC244452.35.

Autosomal genes at a single copy (total copy number 1): 4,876. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
